Surgical pathology report (de-identified scan), TCGA case TCGA-G4-6321, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G4-6321-01A (Primary Tumor).

[page 1 of 3]
SPECIMENS:

A. RIGHT COLON

AMENDMENT REASON

:

This case was amended to correct a formatting error. No other changes were made to this report.

SPECIMEN(S):

A. RIGHT COLON

GROSS DESCRIPTION:

A. RIGHT COLON

Received without fixative, labeled "right colon", is an ilealcolectomy specimen including one segment of 6-cm long ileum, 3.5-cm cecum with attached 6-cm long appendix, 30-cm long colon, with attached mesenteric fat. The colon is approximately 3.5 cm in diameter. Both resection margins are stapled closed. After removal of the stapled line, the specimen is opened and reveals one polypoid ulcerated colonic lesion measures 2.2 x 1.5-cm and elevated above the colonic mucosa to 0.7 cm. This lesion is 11-cm to the colonic resection margin and 19-cm to ileal resection margin. The lesion appears to be superficial and does not involve the colonic wall. Three additional polypoid areas are present and each measuring 1.2, 1.5 and 2-cm in greatest dimension and are located 3.5, 4.5, and 8.0-cm to the colonic resection margin. The uninvolved colonic mucosa and ileal mucosa are unremarkable. The appendix is 6-cm in length and 0.5-cm in diameter and is grossly unremarkable. Multiple possible lymph nodes are present in the mesentery fat. Representative sections are submitted as follows:

A1. Distal colonic resection margin

A2. Proximal ileal resection margin

A3-A4: Full thickness of ulcerated polypoid lesion with attached mesenteric fat (inked black), bisected

A5. Additional section of ulcerated polypoid lesion

A6. Sections from polypoid area, 8.0-cm to the colonic resection margin

A7. Sections from polypoid area, 4.5-cm to the colonic resection margin

A8. Sections from polypoid area, 3.5-cm to the colonic resection margin

A9. Sections of ileum

A10. Sections of cecum and appendix

A11. Ileocecal valve

A12-A14: Random sections of uninvolved colon

A15-A27: Multiple possible lymph nodes

A28: Tip of appendix

DIAGNOSIS:

A. COLON AND TERMINAL ILEUM, RIGHT HEMICOLECTOMY:

- INFILTRATING MODERATELY DIFFERENTIATED ADENOCARCINOMA ARISING IN A SERRATED ADENOMA (2.2-CM)

- SURGICAL MARGINS ARE NOT INVOLVED

- METASTATIC CARCINOMA INVOLVING THREE LYMPH NODES (3/44)

SYNOPTIC REPORT - COLON & RECTUM

Specimens Involved

Specimens: A: RIGHT COLON

Specimen Type: Right hemicolectomy

Tumor Site: Cecum

Tumor Configuration: Exophytic (polypoid)

Tumor size: 2.2cm Additional dimensions 1.5cm x 0.7cm

WHO Classification

Adenocarcinoma 8140/3

Histologic Grade: G2: Moderately differentiated

Extent of Invasion: Muscularis propria

Margins: Margin(s) uninvolved by invasive carcinoma (Proximal, Distal, Radial)

Distance of invasive carcinoma from closest margin: 11cm

Margin: distal

Venous/Lymphatic Invasion: Absent

[page 2 of 3]
Perineural Invasion: Absent
Additional Pathologic Findings: three hyperplastic polyps
Extent of Resection: R0: Complete resection with grossly and microscopically negative margins
Lymph Nodes: Positive 3 / 44
Extranodal extension: Absent
Implants: Absent
Pathological Staging (pTNM): pT 2 N 1 M x
Comment(s):
The tumor has a minor mucinous component with occasional, rare signet ring cells present..
Immunohistochemical studies were performed in blocks A3/A4-see below- to confirm presence of metastatic disease and assess depth of invasion. Further studies to assess microsatellite instability will be reported as an addendum.

SUMMARY OF IMMUNOHISTOCHEMISTRY/SPECIAL STAINS

Material: Block A3
Population: Tumor Cells

Stain/Marker:	Result:	Comment:
CYTOKERATIN AE1/3		Positive

Material: Block A4
Population: Tumor Cells

Stain/Marker:	Result:	Comment:
CYTOKERATIN AE1/3		Positive

The interpretation of the above immunohistochemistry stain or stains is guided by published results in the medical literature, provided package information from the manufacturer and by internal review of staining performance and assay validation within the Immunohistochemistry Laboratory of. The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR). These tests were developed and their performance characteristic determined by the Department of Pathology Laboratory at. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

Special stains and/or immunohistochemical stains were performed with appropriately stained positive and negative controls.

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Colon cancer

ADDENDUM:

SUMMARY OF IMMUNOHISTOCHEMISTRY/SPECIAL STAINS

Material: Specimen A
Population: Tumor Cells

[page 3 of 3]
Stain/Marker:	Result:	Comment:
MLH1	Positive	
MSH2	Positive	
PMS2	Negative	
MSH6	Positive	

The interpretation of the above immunohistochemistry stain or stains is guided by published results in the medical literature, provided package information from the manufacturer and by internal review of staining performance and assay validation within the Immunohistochemistry Laboratory of the. The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR). These tests were developed and their performance characteristic determined by the Department of Pathology Laboratory. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

Special stains and/or immunohistochemical stains were performed with appropriately stained positive and negative controls.

INTERPRETATION: No PMS2 proteins identified by immunohistochemistry.

The results of microsatellite instability testing will be issued in a separate report.

Source: NCI Genomic Data Commons file 0172007d-ca4b-473d-aef1-0373f8e18886 (TCGA-G4-6321.9BD063BF-9893-40C8-8C56-0493A760E439.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).